Somatic mutation profile of tumor specimen 42d860a3-8a0c-4c44-a09a-9ad8cf (aliquot 42d860a3-8a0c-4c44-a09a-9ad8cf_D6) from CPTAC case 04OV001, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC.
Specimen 42d860a3-8a0c-4c44-a09a-9ad8cf: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70b4a16f-f66f-4ffc-b2b3-ae90aa971c59.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 02f6afea-1e5b-4151-bafd-c577d3 (Blood Derived Normal), aliquot 02f6afea-1e5b-4151-bafd-c577d3_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/514de665-e855-4b23-a14c-25d73fe7c0b8

The open-access MAF lists 77 somatic variants for this specimen: 49 protein-altering or splice-affecting, 11 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 11, Intron 5, 5'UTR 4, Frame Shift Del 3, In Frame Del 3, 3'UTR 3, 5'Flank 3, 3'Flank 2, Splice Site 2, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB8 | c.526G>A p.V176M (on ENST00000297504 / NM_001282291.2; = p.V159M on NM_007188.5) | Missense Mutation (SNP) | VAF 84/151 reads (56%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.782); catalogued as rs540495352, COSV52507126; called by muse, mutect2, varscan2
- ASPM | c.7366C>T p.H2456Y | Missense Mutation (SNP) | VAF 54/660 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as rs1158209678; called by muse, mutect2
- CIR1 | c.503C>T p.S168L | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs368845515; called by muse, mutect2, varscan2
- GBA2 | c.1073C>T p.T358M | Missense Mutation (SNP) | VAF 57/159 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.618); catalogued as rs372699319; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HOXD8 | c.257G>A p.R86K | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as rs1446205974; called by muse, mutect2
- LIFR | c.2803G>T p.D935Y | Missense Mutation (SNP) | VAF 92/159 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV54691776; called by muse, mutect2, varscan2
- LRGUK | c.2141G>C p.S714T | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV99604209; called by mutect2, varscan2
- LRRFIP1 | c.2057C>T p.S686L (on ENST00000392000 / NM_001137552.2; = p.S662L on NM_004735.4) | Missense Mutation (SNP) | VAF 96/148 reads (65%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1206389508; called by muse, mutect2, varscan2
- LYST | c.8001G>C p.L2667F | Missense Mutation (SNP) | VAF 134/186 reads (72%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.787); catalogued as COSV67704188; called by muse, mutect2, varscan2
- NES | c.4082G>A p.R1361H | Missense Mutation (SNP) | VAF 93/209 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs780998576; called by muse, mutect2, varscan2
- NLRP5 | c.482A>G p.Q161R | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.527); catalogued as COSV66766565; called by muse, mutect2, varscan2
- PMEPA1 | c.288G>C p.E96D | Missense Mutation (SNP) | VAF 82/396 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV55694393; called by muse, mutect2, varscan2
- RUVBL2 | c.479A>G p.K160R | Missense Mutation (SNP) | VAF 85/190 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.107); catalogued as rs778458331, COSV55488450; called by muse, mutect2, varscan2
- TCHH | c.3196G>A p.E1066K | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.461); catalogued as rs1284895679, COSV64276263; called by muse, varscan2
- TENM4 | c.5553G>T p.K1851N | Missense Mutation (SNP) | VAF 168/320 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53611678, COSV53669725; called by muse, mutect2, varscan2
- TP53 | c.331dup p.L111Pfs*38 | Frame Shift Ins (INS) | VAF 60/103 reads (58%) | catalogued as COSV99036515; called by mutect2, pindel, varscan2
- YDJC | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as rs768322918, COSV53038634; called by muse, mutect2, varscan2
- ZNF121 | c.113C>G p.T38S | Missense Mutation (SNP) | VAF 57/170 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.028); catalogued as rs1338006983; called by muse, mutect2, varscan2
- ZNF805 | c.1838C>G p.S613C | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as rs750901842, COSV62832477; called by muse, mutect2, varscan2
- ACE | c.1586+1G>T p.X529_splice | Splice Site (SNP) | VAF 19/196 reads (10%) | called by muse, mutect2, varscan2
- AP5Z1 | c.2175G>C p.K725N | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BTBD11 | c.1999C>A p.Q667K (on ENST00000280758 / NM_001018072.2; = p.Q204K on NM_001017523.2) | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CHST3 | c.587T>G p.F196C | Missense Mutation (SNP) | VAF 247/688 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- CSMD1 | c.3826+1del p.X1276_splice (on ENST00000520002; = p.X1275_splice on NM_033225.6) | Splice Site (DEL) | VAF 16/43 reads (37%) | called by mutect2, pindel, varscan2
- DENND2A | c.596C>G p.S199C | Missense Mutation (SNP) | VAF 67/221 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- DPP10 | c.226A>T p.R76W | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- FMN2 | c.4414G>C p.E1472Q | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- KCNH7 | c.3398A>C p.N1133T | Missense Mutation (SNP) | VAF 100/298 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- KDM6B | c.1569G>C p.E523D | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRBOX1 | c.144T>G p.Y48* | Nonsense Mutation (SNP) | VAF 36/98 reads (37%) | called by muse, mutect2, varscan2
- LCE3A | c.136A>G p.S46G | Missense Mutation (SNP) | VAF 145/383 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MINDY4 | c.2164A>G p.T722A | Missense Mutation (SNP) | VAF 68/175 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- NIPA1 | c.668G>C p.S223T | Missense Mutation (SNP) | VAF 80/140 reads (57%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- NPC1L1 | c.1941C>G p.I647M | Missense Mutation (SNP) | VAF 256/656 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR2A7 | c.710_712del p.F237del | In Frame Del (DEL) | VAF 139/1002 reads (14%) | called by mutect2, pindel, varscan2
- OTOG | c.5636C>G p.P1879R | Missense Mutation (SNP) | VAF 134/222 reads (60%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- PCDHA8 | c.400del p.R134Gfs*2 | Frame Shift Del (DEL) | VAF 331/537 reads (62%) | called by mutect2, pindel, varscan2
- PLEC | c.9432_9479del p.R3145_A3160del (on ENST00000322810 / NM_201380.4; = p.R3035_A3050del on NM_000445.5) | In Frame Del (DEL) | VAF 147/695 reads (21%) | called by mutect2, pindel
- PRAMEF18 | c.814C>A p.L272I | Missense Mutation (SNP) | VAF 80/535 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- RTF1 | c.1792C>A p.Q598K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.678); called by muse, varscan2
- SEMA3E | c.31C>T p.L11F | Missense Mutation (SNP) | VAF 88/251 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- SLC4A10 | c.1102del p.T368Pfs*27 (on ENST00000446997 / NM_001354461.2; = p.T338Pfs*27 on NM_022058.4 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 13/39 reads (33%) | called by mutect2, pindel, varscan2
- SPATA2L | c.1250A>G p.Y417C | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- SPTA1 | c.1234C>G p.H412D | Missense Mutation (SNP) | VAF 291/707 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTN | c.89859C>A p.S29953R (on ENST00000591111; = p.S22529R on NM_003319.4) | Missense Mutation (SNP) | VAF 38/105 reads (36%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TTN | c.61604_61643del p.S20535Lfs*7 (on ENST00000591111; = p.S13111Lfs*7 on NM_003319.4) | Frame Shift Del (DEL) | VAF 82/300 reads (27%) | called by mutect2, pindel
- UBR3 | c.2851_2862del p.V951_L954del | In Frame Del (DEL) | VAF 9/53 reads (17%) | called by mutect2, pindel, varscan2
- ZNF33A | c.195A>C p.Q65H | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ZNF479 | c.403T>A p.Y135N | Missense Mutation (SNP) | VAF 113/294 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- ANKRD35 | c.642T>C p.A214= | Silent (SNP) | VAF 12/152 reads (8%) | called by muse, mutect2
- ATXN10 | c.27C>T p.A9= | Silent (SNP) | VAF 95/237 reads (40%) | catalogued as rs879701306; called by muse, mutect2, varscan2
- CBLB | c.2925A>C p.P975= | Silent (SNP) | VAF 61/208 reads (29%) | called by muse, mutect2, varscan2
- FAM151B | c.15T>G p.A5= | Silent (SNP) | VAF 43/74 reads (58%) | called by mutect2, varscan2
- FAM155B | c.741C>T p.I247= | Silent (SNP) | VAF 49/171 reads (29%) | catalogued as rs775270963; called by muse, mutect2, varscan2
- INTS7 | c.1626C>G p.A542= | Silent (SNP) | VAF 42/70 reads (60%) | catalogued as rs1324757038; called by muse, mutect2, varscan2
- ITGB4 | c.3522C>T p.L1174= | Silent (SNP) | VAF 508/644 reads (79%) | catalogued as rs760010607; called by muse, mutect2, varscan2
- ITIH3 | c.1368C>A p.A456= | Silent (SNP) | VAF 14/43 reads (33%) | called by muse, mutect2, varscan2
- LAMB4 | c.4281C>A p.S1427= | Silent (SNP) | VAF 62/160 reads (39%) | catalogued as COSV99226096; called by mutect2, varscan2
- TM4SF20 | c.39C>T p.F13= | Silent (SNP) | VAF 63/98 reads (64%) | catalogued as rs751089450; called by muse, mutect2, varscan2
- UBB | c.567C>T p.P189= | Silent (SNP) | VAF 19/203 reads (9%) | catalogued as rs759167895, COSV56218064; ClinVar: likely benign; called by mutect2, varscan2
- AP000356.3 | chr22:24645709 C>G | 5'Flank (SNP) | VAF 34/441 reads (8%) | catalogued as rs1245259912; called by muse, mutect2
- ARMCX4 | c.1038+3072G>A | Intron (SNP) | VAF 41/114 reads (36%) | called by muse, mutect2, varscan2
- CRB3 | chr19:6467001 del GCAGG | 3'Flank (DEL) | VAF 13/85 reads (15%) | called by mutect2, varscan2
- CYHR1 | c.246+65G>A | Intron (SNP) | VAF 187/498 reads (38%) | called by muse, mutect2, varscan2
- DDX11 | c.2052+32C>A | Intron (SNP) | VAF 155/252 reads (62%) | called by muse, mutect2, varscan2
- DMTN | c.*619G>A | 3'UTR (SNP) | VAF 107/306 reads (35%) | called by muse, mutect2, varscan2
- DTNBP1 | c.-58G>A | 5'UTR (SNP) | VAF 71/219 reads (32%) | catalogued as rs1412191992; called by muse, mutect2, varscan2
- ENY2 | c.-1G>C | 5'UTR (SNP) | VAF 39/219 reads (18%) | called by muse, mutect2, varscan2
- FAM230G | n.238-761C>T | Intron (SNP) | VAF 31/154 reads (20%) | catalogued as rs201836920; called by muse, mutect2, varscan2
- GTF2IP1 | n.2314-9C>T | Intron (SNP) | VAF 52/265 reads (20%) | called by muse, mutect2, varscan2
- LAPTM4B | c.-146C>T | 5'UTR (SNP) | VAF 52/99 reads (53%) | called by muse, mutect2, varscan2
- ORMDL2 | c.-57T>G | 5'UTR (SNP) | VAF 32/93 reads (34%) | catalogued as rs1280437597; called by muse, mutect2, varscan2
- PCDH15 | c.*29A>C | 3'UTR (SNP) | VAF 51/122 reads (42%) | catalogued as rs551694595; called by muse, mutect2, varscan2
- PTGES2 | chr9:128128303 C>T | 5'Flank (SNP) | VAF 31/78 reads (40%) | called by muse, mutect2, varscan2
- RUNX1 | chr21:34892932 G>A | 5'Flank (SNP) | VAF 44/108 reads (41%) | catalogued as rs1389232913; called by muse, mutect2, varscan2
- TMEM135 | c.*2680_*2713del | 3'UTR (DEL) | VAF 88/361 reads (24%) | called by mutect2, pindel, varscan2
- UTS2B | chr3:191262896 del AATATGGAAGATGCTTCACTG | 3'Flank (DEL) | VAF 20/109 reads (18%) | called by mutect2, pindel, varscan2
